CCDI case PBCHLY — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Eye and adnexa.
https://portal.gdc.cancer.gov/cases/dd54992c-6253-4ecd-a69c-4e21a6dfb796

Demographics
Sex at birth: female; Race: asian.

Diagnoses (1)
1. Retinoblastoma, NOS: ICD-O-3 morphology code: 9510/3; Tissue or organ of origin: Orbit, NOS; Age at diagnosis: 2.7 years (969 days).

Biospecimens (3 samples)
- Sample 0DU4UL: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DU4V0: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DU4VE: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
